Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A2G5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A2G5-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology

REVISED REPORT (Revised information underlined) 105-0-3

Adenocarcinoma, endometrioid, NOS
8380/3

Site: endometrium C54.1

TISSUE DESCRIPTION:

B1 B2 B3 B4 B5 B6 B7 C1 C2 C3 C4 C5 C6 C7 C8 C9
C10 C11 D1
D2 D3 D4 D5 D6 D7 D8 D9 D10 D11 D12 D13 E1 E2 E3 F1 G1 H1
I1

Uterus, right ovary (2.0 x 1.9 x 1.3 cm) with 8.8 cm
segment of
right fallopian tube, and left ovary (3.2 x 2.1 x 1.3 cm)
with 8.5
cm segment of left fallopian tube together weighing 200.0
grams;
previously submitted tissue from the abdomen (skin and
subcutaneous
tissue without umbilicus, 2305.0 grams); right and left
pelvic lymph
nodes; right and left para-aortic lymph nodes above and
below the
inferior mesenteric artery; right gonadal vessels (10.2 cm
in
length).

DIAGNOSIS:

Uterus, hysterectomy: FIGO grade III (of III) endometrial
adenocarcinoma, endometrioid type, forming an 8.4 x 3.5 x
2.4 cm
polypoid mass filling the endometrial cavity. The tumor
infiltrates
0.4 cm into the myometrium (total myometrial thickness,
2.0 cm).
Angiolymphatic invasion is not identified. Multiple (2)
intramural
leiomyomata (2.3 cm and 1.2 cm in greatest dimension) are
identified. The cervix is uninvolved by tumor.

Ovary and fallopian tube, right and left, salpingo-
oophorectomy:

Without diagnostic abnormality.

Lymph nodes, right pelvic, excision: A single (1 of 5)
right
external iliac lymph node is positive for a microscopic
focus of

[page 2 of 3]
metastatic adenocarcinoma. Multiple right pelvic lymph nodes (2 internal iliac, 3 common iliac, 9 obturator) are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (4 external iliac, 2 internal iliac, 5 common iliac, 7 obturator) are negative for tumor.

Lymph nodes, right and left para-aortic, lymphadenectomy: Multiple para-aortic lymph nodes above the inferior mesenteric artery (5 right, 5 left) are negative for tumor. Multiple para-aortic lymph nodes (3 additional right, 2 right below the inferior mesenteric artery) are negative for tumor.

Gonadal vessel, right, excision: The right gonadal vessel is negative for tumor.

Skin and subcutaneous tissue, abdomen, excision: Skin and subcutaneous tissue without umbilicus (2305.0 grams) identified grossly.

AMENDMENTS: (Previous Signout Date:)
Revision Description: On deeper permanent sections, a single (1 of 5) right external iliac lymph node shows a microscopic focus of metastatic adenocarcinoma.
....Original Diagnosis....
Uterus, hysterectomy: FIGO grade III (of III) endometrial adenocarcinoma, endometrioid type, forming an 8.4 x 3.5 x 2.4 cm polypoid mass filling the endometrial cavity. The tumor infiltrates 0.4 cm into the myometrium (total myometrial thickness, 2.0 cm).
Angiolymphatic invasion is not identified. Multiple (2) intramural

[page 3 of 3]
leiomyomata (2.3 cm and 1.2 cm in greatest dimension) are identified. The cervix is uninvolved by tumor.

Ovary and fallopian tube, right and left, salpingo-oophorectomy:

Without diagnostic abnormality.

Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (5 external iliac, 2 internal iliac, 3 common iliac, 9 obturator) are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (4 external iliac, 2 internal iliac, 5 common iliac, 7 obturator) are negative for tumor.

Lymph nodes, right and left para-aortic, lymphadenectomy: Multiple para-aortic lymph nodes above the inferior mesenteric artery (5 right, 5 left) are negative for tumor. Multiple para-aortic lymph nodes (3 additional right, 2 right below the inferior mesenteric artery) are negative for tumor.

Gonadal vessel, right, excision: The right gonadal vessel is negative for tumor.

Skin and subcutaneous tissue, abdomen, excision: Skin and subcutaneous tissue without umbilicus (2305.0 grams) identified grossly.

Source: NCI Genomic Data Commons file b1eadf59-5be1-465f-acfb-f4772b591466 (TCGA-D1-A2G5.741AB1D9-493E-4659-BC2E-BF77A7E1CC14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).